Somatic mutation profile of tumor specimen 0DN1D0 from CCDI case PBCAUR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.0 years (5,838 days).
Specimen 0DN1D0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8bfd812-f18d-4203-af89-95bc1955a7b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN1B2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dda4102c-e319-47b7-ba98-c40a0df99210

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO6 | c.3526C>T p.R1176* (on ENST00000369981; = p.R1166* on NM_004999.4) | Nonsense Mutation (SNP) | VAF 56/1042 reads (5%) | catalogued as rs121912558, CM031294; ClinVar: pathogenic; called by muse, mutect2
- GNA13 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.271); catalogued as COSV101457417, COSV71474827; called by muse, mutect2, varscan2
- POLD1 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 161/349 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs751775497, COSV70955571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRT37 | c.882G>T p.W294C | Missense Mutation (SNP) | VAF 31/916 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GFAP | c.1171+19C>A | Intron (SNP) | VAF 206/525 reads (39%) | catalogued as rs376484718; called by muse, mutect2, varscan2
- IKBKE | c.1835+83C>G | Intron (SNP) | VAF 8/137 reads (6%) | called by muse, mutect2
